Somatic mutation profile of tumor specimen TCGA-UF-A7JD-01A (aliquot TCGA-UF-A7JD-01A-11D-A34J-08) from TCGA case TCGA-UF-A7JD, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cheek mucosa; AJCC pathologic stage: Stage IVA; Tumor grade: G3; Age at diagnosis: 71.5 years (26,101 days).
Specimen TCGA-UF-A7JD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2318bf4b-7166-4ab9-9eb0-997c30527d90.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-UF-A7JD-10A (Blood Derived Normal), aliquot TCGA-UF-A7JD-10A-01D-A34M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c3c110e8-3c08-4ba8-8f50-6fa975175997

The open-access MAF lists 119 somatic variants for this specimen: 93 protein-altering or splice-affecting, 24 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 84, Silent 24, Nonsense Mutation 3, Frame Shift Del 2, Splice Site 2, RNA 2, In Frame Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALK | c.1202G>T p.R401L | Missense Mutation (SNP) | VAF 17/98 reads (17%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as COSV66560684, COSV66576644; called by muse, mutect2, varscan2
- CTCF | c.610dup p.T204Nfs*26 | Frame Shift Ins (INS) | VAF 28/78 reads (36%) | catalogued as rs886041997; ClinVar: pathogenic; called by mutect2, varscan2
- TP53 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 38/63 reads (60%) | hotspot (GDC flag); catalogued as rs397516436, CM951226, COSV52665560, COSV52740638, COSV52746781, COSV52782151; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA1 | c.2752G>A p.G918S | Missense Mutation (SNP) | VAF 22/129 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.806); catalogued as COSV101037336; called by muse, mutect2, varscan2
- ACBD3 | c.1069G>T p.A357S | Missense Mutation (SNP) | VAF 98/200 reads (49%) | SIFT tolerated (0.41); PolyPhen benign (0.154); catalogued as COSV100831089; called by muse, mutect2, varscan2
- ADAM20 | c.1808C>T p.P603L | Missense Mutation (SNP) | VAF 59/222 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.178); catalogued as COSV56454565, COSV99833512; called by muse, mutect2, varscan2
- AGGF1 | c.686A>G p.N229S | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.5); PolyPhen benign (0.134); catalogued as COSV100462094; called by muse, mutect2, varscan2
- ANGPT4 | c.568C>G p.Q190E | Missense Mutation (SNP) | VAF 7/96 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.057); catalogued as COSV101124830, COSV67921490; called by muse, mutect2
- ANKRD30A | c.1736A>T p.D579V (on ENST00000611781; = p.D523V on NM_052997.2) | Missense Mutation (SNP) | VAF 22/325 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as COSV100654072, COSV64609750; called by muse, mutect2
- APOB | c.6682G>A p.D2228N | Missense Mutation (SNP) | VAF 7/111 reads (6%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as COSV104373509, COSV99266768; called by muse, mutect2
- ARL1 | c.511G>T p.E171* | Nonsense Mutation (SNP) | VAF 35/212 reads (17%) | catalogued as COSV55370078, COSV99880370; called by muse, mutect2, varscan2
- ATP4A | c.431C>A p.A144E | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.51); catalogued as COSV99382863; called by muse, mutect2, varscan2
- BIRC2 | c.111A>C p.Q37H | Missense Mutation (SNP) | VAF 2067/2176 reads (95%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV99926818; called by muse, mutect2, varscan2
- BOD1L1 | c.9047C>A p.T3016K | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.115); catalogued as COSV99239928; called by muse, mutect2, varscan2
- C1orf112 | c.2315A>G p.E772G | Missense Mutation (SNP) | VAF 8/89 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV99610006; called by muse, mutect2
- C9 | c.1105C>T p.R369W | Missense Mutation (SNP) | VAF 43/121 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as rs149784324; called by muse, mutect2, varscan2
- CA7 | c.712G>A p.D238N | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.358); catalogued as rs772935023, COSV100623792; called by muse, mutect2, varscan2
- CATSPERE | c.710G>A p.S237N | Missense Mutation (SNP) | VAF 28/268 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs777560918, COSV100835274; called by muse, mutect2
- CHRNB3 | c.256A>G p.T86A | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.47); PolyPhen benign (0.08); catalogued as COSV99251338; called by muse, mutect2, varscan2
- CRB1 | c.3176C>A p.T1059K | Missense Mutation (SNP) | VAF 15/148 reads (10%) | SIFT tolerated (0.84); PolyPhen benign (0.076); catalogued as COSV100958004; called by muse, mutect2, varscan2
- DNAH9 | c.7823G>A p.R2608H | Missense Mutation (SNP) | VAF 54/333 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs766593497, COSV99306951; called by muse, mutect2, varscan2
- DPRX | c.566G>T p.R189L | Missense Mutation (SNP) | VAF 24/176 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as COSV100934105; called by muse, mutect2, varscan2
- DRD5 | c.449G>T p.R150L | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100431930, COSV58576842; called by muse, mutect2, varscan2
- EPHA5 | c.1132A>C p.I378L | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as COSV99900110; called by muse, mutect2, varscan2
- EPHA7 | c.1640C>T p.A547V | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs1380030438, COSV65186949; called by muse, mutect2
- FAT3 | c.12035C>T p.T4012M | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.967); catalogued as COSV99968206; called by muse, mutect2
- FCAR | c.206G>A p.R69Q | Missense Mutation (SNP) | VAF 40/99 reads (40%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs140716224; called by muse, mutect2, varscan2
- FGD2 | c.843C>A p.F281L | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.696); catalogued as COSV99236429; called by muse, mutect2, varscan2
- FLVCR1 | c.1564A>G p.I522V | Missense Mutation (SNP) | VAF 51/308 reads (17%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs774750073, COSV100875095; called by muse, mutect2, varscan2
- GP1BA | c.1019C>T p.S340F | Missense Mutation (SNP) | VAF 67/177 reads (38%) | SIFT tolerated (0.76); PolyPhen possibly damaging (0.447); catalogued as COSV99851092; called by muse, mutect2, varscan2
- GPR37L1 | c.232C>G p.P78A | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.045); catalogued as COSV100938575, COSV100938623; called by muse, mutect2
- GPR83 | c.214G>A p.A72T | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.575); catalogued as COSV99703811; called by muse, mutect2, varscan2
- GXYLT1 | c.954A>T p.Q318H | Missense Mutation (SNP) | VAF 27/183 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99788812; called by muse, mutect2, varscan2
- H2BC4 | c.266C>G p.T89S | Missense Mutation (SNP) | VAF 111/261 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.268); catalogued as COSV100020007; called by muse, mutect2, varscan2
- H3C8 | c.110A>T p.K37M | Missense Mutation (SNP) | VAF 30/134 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.357); catalogued as COSV59953250; called by muse, mutect2, varscan2
- HRNR | c.6119C>T p.S2040F | Missense Mutation (SNP) | VAF 102/974 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs766681813, COSV64260603; called by muse, mutect2, varscan2
- ITM2B | c.590A>G p.Y197C | Missense Mutation (SNP) | VAF 51/144 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770332292, COSV101052352; called by muse, mutect2, varscan2
- KATNIP | c.395G>A p.R132Q | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as rs748470951, COSV99851628; called by muse, varscan2
- KCNB2 | c.390G>T p.E130D | Missense Mutation (SNP) | VAF 71/147 reads (48%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.773); catalogued as COSV101578880; called by muse, mutect2, varscan2
- KCND2 | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 81/324 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.909); catalogued as COSV58579127; called by muse, mutect2, varscan2
- KCNJ13 | c.170T>C p.M57T | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.053); catalogued as rs1413398896, COSV99289367; called by muse, mutect2, varscan2
- KDR | c.2434C>T p.P812S | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99818242; called by muse, mutect2, varscan2
- LAMA1 | c.6315G>C p.L2105F | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101057059; called by muse, mutect2, varscan2
- LARP1 | c.1378-1G>T p.X460_splice (on ENST00000518297 / NM_033551.3; = p.X383_splice on NM_015315.5 and 6 other RefSeq transcripts) | Splice Site (SNP) | VAF 19/107 reads (18%) | catalogued as COSV100303951; called by muse, mutect2, varscan2
- LETM1 | c.1058G>A p.R353H | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100245536; called by muse, mutect2, varscan2
- MED31 | c.323A>G p.Y108C | Missense Mutation (SNP) | VAF 30/208 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99854594; called by muse, mutect2, varscan2
- MFSD10 | c.955A>T p.M319L | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.308); catalogued as COSV99296728; called by muse, mutect2, varscan2
- MOV10 | c.2758G>A p.G920R | Missense Mutation (SNP) | VAF 26/168 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99588428; called by muse, mutect2, varscan2
- MRTFA | c.904A>G p.K302E | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.328); catalogued as COSV100844243; called by muse, mutect2, varscan2
- MYO18B | c.5857G>A p.E1953K | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.163); catalogued as rs374817192, COSV59137393; called by muse, mutect2, varscan2
- MYO5A | c.1190C>A p.T397K | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as COSV100697920, COSV62562393; called by muse, mutect2, varscan2
- NAALADL2 | c.819G>C p.K273N | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.023); catalogued as COSV101458188; called by muse, mutect2, varscan2
- NFATC2 | c.2105T>C p.L702P | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV101044363; called by muse, mutect2, varscan2
- NSMCE4A | c.835C>T p.R279* | Nonsense Mutation (SNP) | VAF 21/82 reads (26%) | catalogued as COSV100940064, COSV100940078; called by muse, mutect2, varscan2
- NSUN6 | c.695C>G p.P232R | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101045805; called by muse, mutect2, varscan2
- NUP133 | c.356G>T p.C119F | Missense Mutation (SNP) | VAF 113/238 reads (47%) | SIFT tolerated (0.18); PolyPhen benign (0.018); catalogued as COSV99773220; called by muse, mutect2, varscan2
- OR5B12 | c.175T>G p.F59V | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.015); catalogued as COSV100222282; called by muse, mutect2, varscan2
- PCDHGA11 | c.2170C>T p.R724C | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.049); catalogued as rs759822483, COSV54042009, COSV99542652; called by muse, mutect2, varscan2
- PCNX1 | c.5726C>T p.S1909F | Missense Mutation (SNP) | VAF 49/194 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1439908325, COSV99456540; called by muse, mutect2, varscan2
- PCNX3 | c.5296C>T p.R1766C | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV63135518; called by muse, mutect2, varscan2
- PDZRN4 | c.2350G>A p.G784R (on ENST00000402685 / NM_001164595.2; = p.G526R on NM_013377.4) | Missense Mutation (SNP) | VAF 32/154 reads (21%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as COSV54203810; called by muse, mutect2, varscan2
- PLXDC1 | c.605T>C p.V202A | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.193); catalogued as COSV100195628; called by muse, mutect2, varscan2
- PLXNA2 | c.3639+1G>T p.X1213_splice | Splice Site (SNP) | VAF 12/79 reads (15%) | catalogued as COSV100885658; called by muse, mutect2, varscan2
- PLXNA2 | c.3639G>T p.M1213I | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT tolerated (0.53); PolyPhen benign (0.03); catalogued as COSV100885659; called by muse, mutect2, varscan2
- PPP1R32 | c.181G>C p.V61L | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.352); catalogued as COSV100087920; called by muse, mutect2
- PRDM9 | c.450A>T p.K150N | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.981); catalogued as COSV99690791; called by muse, mutect2, varscan2
- PRM2 | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 64/186 reads (34%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.044); catalogued as rs768731173, COSV99617749; called by muse, mutect2, varscan2
- RNF216 | c.1186G>A p.E396K (on ENST00000425013 / NM_207116.3; = p.E453K on NM_207111.4) | Missense Mutation (SNP) | VAF 19/153 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.255); catalogued as COSV66289022, COSV66291512; called by muse, mutect2, varscan2
- RYR3 | c.11195G>A p.R3732H (on ENST00000389232; = p.R3733H on NM_001036.6) | Missense Mutation (SNP) | VAF 57/228 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.54); catalogued as rs374140172; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SAC3D1 | c.968G>A p.S323N | Missense Mutation (SNP) | VAF 37/86 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as COSV100101299; called by muse, mutect2, varscan2
- SBF1 | c.901G>A p.D301N | Missense Mutation (SNP) | VAF 45/118 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100817917; called by muse, mutect2, varscan2
- SCARF1 | c.2074T>C p.Y692H | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99557161; called by muse, mutect2, varscan2
- SH3GLB2 | c.634G>T p.D212Y | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.824); catalogued as COSV100999320, COSV100999363; called by muse, mutect2, varscan2
- SH3PXD2A | c.635A>T p.Q212L | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as COSV100280297; called by muse, mutect2, varscan2
- STRN3 | c.2366C>T p.A789V (on ENST00000357479 / NM_001083893.2; = p.A705V on NM_014574.4) | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.142); catalogued as COSV100670807; called by muse, varscan2
- TBC1D31 | c.358A>T p.S120C | Missense Mutation (SNP) | VAF 36/258 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as COSV99782308, COSV99783016; called by muse, mutect2, varscan2
- THAP12 | c.821A>T p.E274V | Missense Mutation (SNP) | VAF 51/123 reads (41%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.91); catalogued as COSV99473139; called by muse, mutect2, varscan2
- TMEM81 | c.276C>A p.F92L | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.34); catalogued as COSV99196765, COSV99196861; called by muse, mutect2, varscan2
- TRIM56 | c.1831G>A p.V611M | Missense Mutation (SNP) | VAF 27/125 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs200430251, COSV100047532; called by muse, mutect2, varscan2
- TRMT2B | c.1417A>G p.K473E | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.292); catalogued as COSV100105561; called by muse, mutect2, varscan2
- TRPC6 | c.2558G>C p.R853T | Missense Mutation (SNP) | VAF 57/423 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100723712; called by muse, mutect2, varscan2
- TTN | c.73712G>T p.R24571I (on ENST00000591111; = p.R17147I on NM_003319.4) | Missense Mutation (SNP) | VAF 51/96 reads (53%) | PolyPhen benign (0.132); catalogued as COSV100621752; called by muse, mutect2, varscan2
- USP25 | c.1580T>C p.I527T | Missense Mutation (SNP) | VAF 7/112 reads (6%) | SIFT tolerated (0.67); PolyPhen benign (0.138); catalogued as COSV99584225; called by muse, mutect2
- WNT6 | c.314C>T p.T105M | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as rs759013954, COSV99293275; called by muse, mutect2, varscan2
- ZFYVE9 | c.2834A>T p.N945I | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99820419; called by muse, mutect2, varscan2
- ZNF835 | c.34G>T p.A12S | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV101606384; called by muse, mutect2, varscan2
- ZW10 | c.1993A>G p.I665V | Missense Mutation (SNP) | VAF 40/153 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV99562790; called by muse, mutect2, varscan2
- CEP170 | c.2465A>G p.K822R | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- EMC2 | c.781G>T p.A261S | Missense Mutation (SNP) | VAF 5/82 reads (6%) | SIFT tolerated (0.47); PolyPhen benign (0.015); called by muse, mutect2
- EPHA2 | c.1145del p.S382Mfs*11 | Frame Shift Del (DEL) | VAF 11/34 reads (32%) | called by mutect2, pindel, varscan2
- IGHG2 | c.54_65del p.S19_T22del | In Frame Del (DEL) | VAF 8/77 reads (10%) | called by mutect2, varscan2
- KCNJ6 | c.523del p.S175Lfs*17 | Frame Shift Del (DEL) | VAF 12/99 reads (12%) | called by mutect2, pindel, varscan2
- NCOA4 | c.957T>A p.N319K | Missense Mutation (SNP) | VAF 23/130 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- APOB | c.5352T>G p.V1784= | Silent (SNP) | VAF 27/179 reads (15%) | catalogued as COSV99266771; called by muse, mutect2, varscan2
- ARMC5 | c.2388G>A p.S796= | Silent (SNP) | VAF 19/66 reads (29%) | catalogued as rs766036690, COSV99192679; called by muse, mutect2, varscan2
- BDKRB2 | c.295C>T p.L99= | Silent (SNP) | VAF 24/210 reads (11%) | catalogued as rs1219461511, COSV100021334; called by muse, mutect2, varscan2
- DHRS4L2 | c.576C>A p.L192= | Silent (SNP) | VAF 62/227 reads (27%) | catalogued as COSV100632573; called by muse, mutect2, varscan2
- EHMT1 | c.1416A>G p.A472= | Silent (SNP) | VAF 70/144 reads (49%) | catalogued as COSV100604079; called by muse, mutect2, varscan2
- FABP1 | c.117G>A p.S39= | Silent (SNP) | VAF 54/299 reads (18%) | catalogued as rs770387493, COSV55557805; called by muse, mutect2, varscan2
- FSIP2 | c.20241A>G p.R6747= | Silent (SNP) | VAF 45/113 reads (40%) | catalogued as rs761833322, COSV100555755; called by muse, mutect2, varscan2
- HEATR9 | c.699G>A p.E233= | Silent (SNP) | VAF 15/99 reads (15%) | catalogued as rs555326438; called by muse, mutect2, varscan2
- JAM2 | c.210C>T p.V70= | Silent (SNP) | VAF 30/154 reads (19%) | catalogued as COSV100468526; called by muse, mutect2, varscan2
- KCNS2 | c.957G>A p.G319= | Silent (SNP) | VAF 42/84 reads (50%) | catalogued as COSV54637463, COSV99751040; called by muse, mutect2, varscan2
- MARS1 | c.2256C>G p.L752= | Silent (SNP) | VAF 12/100 reads (12%) | catalogued as rs201540140, COSV100007536; ClinVar: likely benign; called by muse, mutect2, varscan2
- MKS1 | c.822G>A p.P274= | Silent (SNP) | VAF 29/115 reads (25%) | catalogued as rs375557871; called by muse, mutect2, varscan2
- MOB4 | c.189C>G p.G63= | Silent (SNP) | VAF 24/274 reads (9%) | catalogued as COSV99291144; called by muse, mutect2
- NEK9 | c.2784G>A p.Q928= | Silent (SNP) | VAF 69/266 reads (26%) | catalogued as COSV99464312; called by muse, mutect2, varscan2
- NFATC2 | c.2688G>A p.Q896= | Silent (SNP) | VAF 21/330 reads (6%) | catalogued as COSV101044359; called by muse, mutect2
- OXR1 | c.1425A>G p.A475= (on ENST00000442977 / NM_001198532.1; = p.A474= on NM_018002.3) | Silent (SNP) | VAF 10/57 reads (18%) | catalogued as rs1244587175, COSV100367534; called by muse, mutect2, varscan2
- PAPPA2 | c.33G>T p.L11= | Silent (SNP) | VAF 35/187 reads (19%) | catalogued as COSV100866911; called by muse, mutect2, varscan2
- PFAS | c.3675C>T p.A1225= | Silent (SNP) | VAF 18/110 reads (16%) | catalogued as rs370246611; called by muse, mutect2, varscan2
- PRUNE1 | c.390C>T p.I130= | Silent (SNP) | VAF 11/164 reads (7%) | catalogued as rs112180991; called by muse, mutect2
- SLC24A3 | c.396C>T p.F132= | Silent (SNP) | VAF 25/122 reads (20%) | catalogued as rs764961538, COSV60118405, COSV60120466; called by muse, mutect2, varscan2
- SSTR1 | c.615G>A p.T205= | Silent (SNP) | VAF 5/86 reads (6%) | catalogued as rs1177563616, COSV99942991; called by muse, mutect2
- WDR44 | c.2691C>T p.D897= | Silent (SNP) | VAF 30/52 reads (58%) | catalogued as COSV99561770; called by muse, mutect2, varscan2
- YWHAZ | c.594A>G p.E198= | Silent (SNP) | VAF 30/219 reads (14%) | catalogued as COSV62053464; called by muse, mutect2, varscan2
- ZNF800 | c.1629A>G p.K543= | Silent (SNP) | VAF 22/175 reads (13%) | catalogued as COSV99758068; called by muse, mutect2, varscan2
- SSPOP | n.11661C>G | RNA (SNP) | VAF 4/20 reads (20%) | catalogued as rs374846709, COSV100947458, COSV65127369; called by muse, mutect2
- XIST | n.11280G>A | RNA (SNP) | VAF 16/52 reads (31%) | called by muse, mutect2, varscan2
